Surgical pathology report (de-identified scan), TCGA case TCGA-CR-7385, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-7385-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

Accession number: [REDACTED]

Final Report

DIAGNOSIS:

1) TONSIL, LEFT, TONSILLECTOMY: INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA ARISING WITHIN TONSILLAR CRYPTS WITH ASSOCIATED IN SITU CARCINOMA; IN SITU CARCINOMA FOCALLY INVOLVES A CAUTERIZED SURGICAL MARGIN; ALL SURGICAL MARGINS NEGATIVE FOR INVASIVE CARCINOMA; LYMPHOVASCULAR INVASION IDENTIFIED (SEE COMMENT).

Comment: This tumor corresponds to AJCC stage I (pT1, pNx).

**Electronically Signed Out by [REDACTED]

CLINICAL DATA

Clinical Features: Unspecified

Operator: [REDACTED]

Operation: Unspecified

Operative Findings: Unspecified

Operative Diagnosis: Unspecified

Tissue Submitted: 1) left tonsil

GROSS DESCRIPTION:

1) SOURCE: Tonsil, Left

The specimen is received fresh and is labeled, "left tonsil," and it consists of a 5.5 x 1.5 x 1.0 cm fragmented, friable tonsil. The mucosa is red-pink, lobulated, and granular. The margin is inked blue. Sectioning reveals a firm, white cut surface. A portion of this specimen is submitted to research. This firm, lobulated cut surface extends all the way to the inked margin. Representative sections are submitted.

Summary of sections: 1A, 2/1; 1B, 2/1; 1C, 1/1.

Dictated by [REDACTED]

Slides and report reviewed by Attending Pathologist.

Source: NCI Genomic Data Commons file 0b81c731-8fd6-449e-9431-da6212273a54 (TCGA-CR-7385.B39309DC-6B0D-41B0-808B-35283E64BC1E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).